Somatic mutation profile of tumor specimen TCGA-3U-A98J-01A (aliquot TCGA-3U-A98J-01A-11D-A39R-32) from TCGA case TCGA-3U-A98J, project TCGA-MESO (Mesothelioma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Epithelioid mesothelioma, malignant; Tissue or organ of origin: Pleura, NOS; AJCC pathologic stage: Stage III; Age at diagnosis: 55.7 years (20,338 days).
Specimen TCGA-3U-A98J-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4f484f70-b621-412b-a773-040153994e2f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-3U-A98J-10A (Blood Derived Normal), aliquot TCGA-3U-A98J-10A-01D-A39U-32; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/88023e51-e4a2-4cbe-8c3c-a52e98a34897

The open-access MAF lists 25 somatic variants for this specimen: 18 protein-altering or splice-affecting, 6 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 17, Silent 6, Frame Shift Del 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AHNAK | c.11189G>A p.G3730E | Missense Mutation (SNP) | VAF 12/136 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs1401987875; called by muse, mutect2
- ARHGEF2 | c.2630G>A p.R877H (on ENST00000361247 / NM_001162383.2; = p.R849H on NM_004723.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 60/160 reads (38%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.018); catalogued as rs749600621, COSV58107754; called by muse, mutect2, varscan2
- COL26A1 | c.262C>T p.P88S | Missense Mutation (SNP) | VAF 21/96 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.219); catalogued as rs1453539929; called by muse, mutect2, varscan2
- LDB1 | c.708del p.N237Ifs*11 (on ENST00000425280 / NM_001321612.2; = p.N201Ifs*11 on NM_003893.5) | Frame Shift Del (DEL) | VAF 11/84 reads (13%) | catalogued as COSV63290034; called by mutect2, pindel, varscan2
- NFE2L1 | c.2071C>T p.R691C | Missense Mutation (SNP) | VAF 51/190 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs748145897; called by muse, mutect2, varscan2
- PADI4 | c.914C>T p.P305L | Missense Mutation (SNP) | VAF 19/62 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); catalogued as rs755282116, COSV64924407; called by muse, mutect2, varscan2
- SET | c.193G>A p.E65K (on ENST00000372692 / NM_001374326.1; = p.E52K on NM_003011.4) | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.764); catalogued as COSV100433089; called by muse, mutect2, varscan2
- SIGIRR | c.604C>T p.R202C | Missense Mutation (SNP) | VAF 17/111 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.892); catalogued as rs1478443976; called by muse, mutect2
- AMBRA1 | c.3682C>G p.P1228A (on ENST00000458649 / NM_001367468.1; = p.P1138A on NM_017749.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); called by muse, mutect2, varscan2
- ANK2 | c.10612A>G p.I3538V | Missense Mutation (SNP) | VAF 19/71 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- DHX58 | c.1033G>A p.G345S | Missense Mutation (SNP) | VAF 26/77 reads (34%) | SIFT tolerated (0.63); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ELAVL2 | c.344C>A p.A115D | Missense Mutation (SNP) | VAF 17/100 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- FMN2 | c.1960C>A p.Q654K | Missense Mutation (SNP) | VAF 10/87 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- GNAL | c.937C>A p.P313T (on ENST00000269162 / NM_001142339.3; = p.P390T on NM_182978.4) | Missense Mutation (SNP) | VAF 25/99 reads (25%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- MED12 | c.3977A>C p.Y1326S | Missense Mutation (SNP) | VAF 24/36 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- PLA2G4A | c.1550A>T p.D517V | Missense Mutation (SNP) | VAF 25/172 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.082); called by muse, mutect2, varscan2
- STK35 | c.842G>A p.G281D | Missense Mutation (SNP) | VAF 26/158 reads (16%) | SIFT deleterious (0.05); PolyPhen benign (0.348); called by muse, mutect2, varscan2
- WWP2 | c.1154A>T p.H385L | Missense Mutation (SNP) | VAF 17/74 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- ENOX2 | c.1827G>A p.L609= (on ENST00000338144 / NM_001382520.1; = p.L580= on NM_006375.3 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 12/27 reads (44%) | called by muse, mutect2, varscan2
- NLRP6 | c.2382G>T p.L794= | Silent (SNP) | VAF 33/115 reads (29%) | called by muse, mutect2, varscan2
- OR10A2 | c.600G>T p.L200= | Silent (SNP) | VAF 19/71 reads (27%) | called by muse, mutect2, varscan2
- PCDHB13 | c.2076G>A p.V692= | Silent (SNP) | VAF 8/22 reads (36%) | catalogued as COSV99507399; called by muse, mutect2, varscan2
- RAG2 | c.918T>C p.D306= | Silent (SNP) | VAF 33/124 reads (27%) | called by muse, mutect2, varscan2
- RBP3 | c.2031G>A p.V677= | Silent (SNP) | VAF 9/105 reads (9%) | called by muse, mutect2
- AP000769.3 | chr11:65504283 ins G | 5'Flank (INS) | VAF 12/58 reads (21%) | catalogued as rs749683708; called by mutect2, pindel, varscan2
